HCMI case HCM-BROD-0716-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/78b05ced-6b5e-44e0-b8e2-07ab9b69e440

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 58.7 years (21,450 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M1c; AJCC pathologic stage: Stage IV; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 3,160 days (8.7 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C78.4; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Small intestine, NOS; Classification of tumor: metastasis; Age at diagnosis: 67.3 years (24,591 days); Days to diagnosis: 3,141 days (8.6 years); Satellite nodule present: Present.
   Pathology details: Breslow thickness category: >1.0-2.0 mm; Lymph nodes positive: 0; Lymph nodes tested: 3; Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.

Follow-up (2 entries)
- Days to follow up: 3,657 days (10.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 3,362.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600K.
- NRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 84 kg; Height: 177 cm; BMI: 26.8.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0716-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0716-C43-06B-01-S1-HE: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 35; Percent normal cells: 55; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 20.
  Slide HCM-BROD-0716-C43-06B-01-S2-HE: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 40; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 8.
- Sample HCM-BROD-0716-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0716-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
